Gene-level copy-number profile of specimen HCM-BROD-0791-C43-85N from HCMI case HCM-BROD-0791-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 61.0 years (22,298 days).
Specimen HCM-BROD-0791-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3313a915-0d62-47d7-93a0-a1525e56437f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0791-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/2a8f2fd0-ab03-4dc3-9d00-0d768f894093

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 386; copy number 1: 756; copy number 2: 16,641; copy number 3: 30,496; copy number 4: 10,432; copy number 5: 117; copy number 6: 34; copy number 7: 13; copy number 8: 19; copy number 9: 10; copy number 10: 1; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:23,955,760–24,592,104, 3 genes: AL365204.3, IZUMO3, AL353811.1.
- chr9:28,598,668–29,318,952, 5 genes (within-gene range 0–2): KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1.
- chr9:30,388,935–30,671,966, 3 genes: LINC01242, SLC4A1APP1, CDRT15P5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 44 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,392,790–114,995,370, 15 genes, copy number 8: TRIM33, AL035410.1, EIF2S2P5, Y_RNA, PKMP1, BCAS2, DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1.
- chr8:127,794,526–128,187,101, 10 genes, copy number 7 (within-gene range 5–7): PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.
- chr8:128,634,199–129,683,770, 6 genes, copy number 8–9 (within-gene range 3–9): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr8:129,748,196–129,844,504, 2 genes, copy number 10–12 (within-gene range 4–12): GSDMC, AC022973.5.
- chr15:98,437,162–99,105,824, 11 genes, copy number 7–9 (within-gene range 5–9): FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1.

Autosomal genes at a single copy (total copy number 1): 756. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
